Somatic mutation profile of tumor specimen TCGA-A6-2677-01B (aliquot TCGA-A6-2677-01B-02D-A270-10) from TCGA case TCGA-A6-2677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-A6-2677-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb1b3c8-4996-4a34-8a8e-ca871f6ab515.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2677-10A (Blood Derived Normal), aliquot TCGA-A6-2677-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44474211-29c1-4b9a-8b74-a12df770cbff

The open-access MAF lists 139 somatic variants for this specimen: 95 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 42, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 72/191 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3463G>A p.V1155I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs759961510, COSV100216771; called by muse, mutect2, varscan2
- ABHD18 | c.1186C>T p.R396* (on ENST00000398965 / NM_001039717.2; = p.R303* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 56/206 reads (27%) | catalogued as rs149965291; called by muse, mutect2, varscan2
- ABL1 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as rs762470102, COSV100583574; called by muse, mutect2, varscan2
- ACR | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1384373386, COSV99334373; called by muse, mutect2, varscan2
- ACTL7B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs764432169, COSV65927155; called by muse, mutect2, varscan2
- AMY2A | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 45/692 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70214384; called by muse, mutect2
- AP1M2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1202522150, COSV51566479, COSV51568642, COSV99140743; called by muse, mutect2, varscan2
- APC | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 42/115 reads (37%) | catalogued as CM040977, COSV57355920; called by muse, mutect2, varscan2
- APLP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375567499; called by muse, mutect2, varscan2
- ARHGAP15 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1172005459, COSV99709041; called by muse, mutect2, varscan2
- ARHGEF9 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs781858542, COSV53634623; called by muse, mutect2, varscan2
- ATRX | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs376906761, COSV64874330; called by muse, mutect2, varscan2
- AXL | c.2162T>C p.L721P (on ENST00000301178 / NM_021913.5; = p.L712P on NM_001699.6) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996087; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 92/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- BTBD10 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV99533405; called by muse, mutect2, varscan2
- C1R | c.1987G>A p.A663T (on ENST00000536053 / NM_001354346.2; = p.A649T on NM_001733.7) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.111); catalogued as rs1232507665, COSV73383043; called by muse, mutect2, varscan2
- CALCRL | c.985A>C p.N329H | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1018639295, COSV101130893; called by muse, mutect2, varscan2
- COL4A4 | c.4148G>T p.G1383V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100306388; called by muse, mutect2, varscan2
- COL6A3 | c.6869G>A p.R2290H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs398124131, COSV99796521; ClinVar: uncertain significance; called by muse, mutect2
- CYP3A7 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs760875340, COSV60480907; called by muse, mutect2, varscan2
- DSE | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs549153887, COSV59065405; called by muse, mutect2, varscan2
- EXOSC10 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs1176642616, COSV58665211; called by muse, mutect2, varscan2
- FAM47A | c.1804A>T p.R602* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV60493596; called by muse, mutect2, varscan2
- FAT3 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs748097452, COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FOXI2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV59094132; called by muse, mutect2, varscan2
- HTR1E | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1222836067, COSV59508189, COSV59511573; called by muse, mutect2, varscan2
- IARS2 | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV56962907; called by muse, mutect2, varscan2
- IFI35 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.246); catalogued as COSV55896797, COSV99887721; called by muse, mutect2, varscan2
- IGFBP3 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs1284105182, COSV99298211; called by muse, mutect2, varscan2
- INPPL1 | c.2627C>T p.T876M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs367743824; called by muse, mutect2, varscan2
- IRAG1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs374041885; called by muse, mutect2, varscan2
- KLF8 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100808138; called by muse, mutect2, varscan2
- KLHL13 | c.1305C>G p.H435Q | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV99451198; called by muse, mutect2, varscan2
- KLHL15 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100044023; called by muse, mutect2, varscan2
- KLK4 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs777659052, COSV100133555; called by muse, mutect2, varscan2
- MCM10 | c.659G>A p.R220Q (on ENST00000484800 / NM_182751.3; = p.R219Q on NM_018518.5) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs756598324, COSV66333712; called by muse, mutect2, varscan2
- MYT1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100114130; called by muse, mutect2, varscan2
- NANOG | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as COSV57551161; called by muse, mutect2, varscan2
- NBEAL2 | c.5336G>A p.R1779H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1393928806, COSV99434819; called by muse, mutect2, varscan2
- NDST3 | c.1885A>C p.K629Q | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.589); catalogued as COSV99629840; called by muse, mutect2, varscan2
- NKX2-1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as CM136275, COSV61388050, COSV61390583; called by muse, mutect2, varscan2
- NME9 | c.223G>A p.E75K (on ENST00000333911 / NM_001349024.2; = p.E53K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs200732318, COSV58616706; called by muse, mutect2, varscan2
- NOVA1 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946754; called by muse, mutect2, varscan2
- NRK | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 148/350 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779676790, COSV54598219; called by muse, varscan2
- OR1D5 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770608969, COSV101643410; called by muse, mutect2, varscan2
- PCSK2 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as COSV99358901; called by muse, mutect2, varscan2
- PIP5K1C | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs748987470, COSV100095086; called by muse, mutect2, varscan2
- PKHD1 | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs191201723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POGZ | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51851084; called by muse, mutect2, varscan2
- PTPN13 | c.2759T>A p.L920H | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100364226; called by muse, mutect2, varscan2
- PTPN23 | c.3489C>A p.D1163E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99650280; called by muse, varscan2
- PTPRD | c.2215A>C p.K739Q | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.574); catalogued as COSV100643790; called by muse, mutect2, varscan2
- RAD18 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769975828, COSV53748856; called by muse, mutect2, varscan2
- RPTOR | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452445269, COSV60806260, COSV60808190; called by muse, mutect2, varscan2
- SACS | c.10832C>A p.A3611D | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207233; called by muse, mutect2, varscan2
- SCGB3A1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs773272977, COSV53005461; called by muse, mutect2, varscan2
- SERPINI1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.028); catalogued as COSV99854887; called by muse, mutect2, varscan2
- SFRP5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV56603657; called by muse, mutect2, varscan2
- SHCBP1L | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV100840948; called by muse, varscan2
- SLC12A1 | c.1845G>C p.L615F | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV101118336; called by muse, mutect2, varscan2
- SLC12A5 | c.2024C>T p.A675V (on ENST00000454036 / NM_001134771.2; = p.A652V on NM_020708.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1555865828, COSV99715498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F3 | c.631G>A p.A211T (on ENST00000366617 / NM_001300845.1; = p.A280T on NM_173508.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs773044833, COSV64019679; called by muse, mutect2, varscan2
- SLITRK6 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as COSV101233188, COSV68390511; called by muse, mutect2
- SORCS1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1262994826, COSV99544071; called by muse, mutect2, varscan2
- SOX11 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as rs1411163388, COSV100430952, COSV58983614; called by muse, mutect2, varscan2
- SOX17 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs759612481, COSV52026910; called by mutect2, varscan2
- SP140 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs1451524780, COSV59448267; called by mutect2, varscan2
- SPAG17 | c.5858C>T p.S1953F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100308242; called by muse, mutect2, varscan2
- STRA8 | c.260G>A p.W87* (on ENST00000275764; = p.W65* on NM_182489.2) | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs1290153678, COSV99312279; called by muse, mutect2, varscan2
- SULT6B1 | c.418C>T p.R140* (on ENST00000535679 / NM_001367551.1; = p.R102* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as rs147099571, COSV53194210; called by muse, mutect2
- SYNE1 | c.1108C>T p.Q370* (on ENST00000367255 / NM_182961.4; = p.Q377* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99555915; called by muse, mutect2, varscan2
- TAS2R13 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as COSV101183721; called by muse, mutect2, varscan2
- TAS2R14 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV67854403; called by muse, mutect2, varscan2
- TBX22 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100960655; called by muse, mutect2, varscan2
- TMEM185A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382959; called by muse, mutect2, varscan2
- TRIM55 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs754147349, COSV52545616; called by muse, mutect2, varscan2
- TRMT11 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1253146421, COSV100543093; called by muse, mutect2, varscan2
- TTN | c.94499T>A p.L31500H (on ENST00000591111; = p.L24076H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | PolyPhen probably damaging (0.992); catalogued as COSV100598789; called by muse, mutect2, varscan2
- TUBE1 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100036918; called by muse, mutect2, varscan2
- UNC5B | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs202076199; called by muse, mutect2
- VSTM2A | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 5/151 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56492165; called by muse, mutect2
- ZFHX4 | c.2909A>G p.K970R | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV99258194; called by muse, mutect2, varscan2
- ZNF260 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV101591032; called by muse, mutect2, varscan2
- ZNF484 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214500; called by muse, mutect2, varscan2
- ZNF658 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs766547680; called by muse, varscan2
- ANK3 | c.13053dup p.S4352Vfs*2 (on ENST00000280772 / NM_001320874.2; = p.S976Vfs*2 on NM_001149.3) | Frame Shift Ins (INS) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- KARS1 | c.18_20del p.A7del | In Frame Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- OR6S1 | c.96_97del p.F33Sfs*21 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by pindel, varscan2
- PLCD3 | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- SOX9 | c.729_736delinsA p.D244Sfs*7 | Frame Shift Del (DEL) | VAF 54/124 reads (44%) | called by pindel, varscan2*
- SPTY2D1 | c.2054_*4del | Nonstop Mutation (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D22A | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2
- ZC3H13 | c.2274_2283del p.R758Sfs*104 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, varscan2
- ADCY1 | c.2289C>T p.Y763= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs369554390; called by muse, mutect2, varscan2
- ARMC5 | c.930C>T p.A310= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99192352; called by muse, mutect2, varscan2
- AS3MT | c.1101C>T p.G367= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100185601; called by muse, mutect2, varscan2
- CEP350 | c.2031A>G p.Q677= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV62600577; called by muse, mutect2, varscan2
- DKKL1 | c.348G>A p.E116= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV55564050, COSV99678630; called by muse, mutect2, varscan2
- DSCAM | c.1143C>T p.G381= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs372861546; called by muse, mutect2, varscan2
- DVL2 | c.2151C>T p.S717= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs747427559; called by mutect2, varscan2
- EGR1 | c.1440G>A p.S480= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53518683; called by muse, mutect2, varscan2
- EPHX1 | c.690G>A p.L230= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs1431236139, COSV55299140, COSV99688778; called by muse, mutect2, varscan2
- FLNC | c.5361G>T p.L1787= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100367716; called by mutect2, varscan2
- GPR25 | c.297G>A p.A99= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58497899; called by muse, mutect2, varscan2
- HELQ | c.192G>A p.Q64= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs1178892854, COSV55024416; called by muse, mutect2, varscan2
- IL22RA2 | c.417G>A p.S139= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs140915731; called by muse, mutect2, varscan2
- ITGA10 | c.1392G>A p.Q464= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100994760; called by muse, mutect2, varscan2
- KIAA1210 | c.3741T>C p.P1247= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs746934065, COSV101273956; called by muse, mutect2, varscan2
- KIAA1614 | c.2739G>A p.P913= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs376502384; called by muse, mutect2, varscan2
- KNDC1 | c.3306C>T p.C1102= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100463668; called by muse, mutect2, varscan2
- LAMC3 | c.915G>T p.L305= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV63096733; called by muse, mutect2
- MED12 | c.1920T>C p.P640= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61336149; called by muse, mutect2, varscan2
- NDN | c.108G>A p.A36= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV59359485, COSV59359551; called by muse, mutect2, varscan2
- NLRP4 | c.699C>T p.F233= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs577037043, COSV56708587; called by muse, mutect2, varscan2
- NPTX1 | c.1251C>T p.Y417= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as rs768903811, COSV60774392; called by muse, mutect2, varscan2
- PCDH10 | c.939C>T p.S313= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs769286962, COSV99993129; called by muse, mutect2, varscan2
- PCDHA9 | c.1974G>A p.A658= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs782339078, COSV65333380; called by muse, mutect2, varscan2
- PCDHB15 | c.1581C>T p.F527= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as rs782103267, COSV50929775; called by muse, mutect2, varscan2
- PCDHB6 | c.471C>T p.H157= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV50692043; called by muse, mutect2, varscan2
- PGF | c.375C>T p.H125= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs749171908, COSV53125108; called by muse, mutect2, varscan2
- PKP2 | c.597C>A p.I199= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV50727106, COSV50728255; called by muse, mutect2, varscan2
- POTEA | c.114C>T p.S38= | Silent (SNP) | VAF 60/120 reads (50%) | called by muse, mutect2, varscan2
- SELENOM | c.399G>A p.A133= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100294083; called by muse, mutect2, varscan2
- SLC24A2 | c.594C>T p.I198= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs758224147, COSV53865048; called by muse, mutect2, varscan2
- SLC6A3 | c.1608C>T p.V536= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs772870958, COSV54367789; called by muse, mutect2
- SPA17 | c.27C>T p.H9= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs368335369; called by muse, mutect2, varscan2
- STAB2 | c.6552C>T p.D2184= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs577176538, COSV66335510; ClinVar: likely benign; called by muse, mutect2, varscan2
- STIM2 | c.2169C>T p.D723= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99402205; called by muse, mutect2, varscan2
- SUV39H1 | c.837C>T p.T279= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100551696; called by muse, mutect2, varscan2
- TMEM132D | c.1593C>T p.S531= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs376143160; called by muse, mutect2, varscan2
- TMEM63B | c.477C>T p.I159= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1383525673, COSV99441138; called by muse, mutect2, varscan2
- TNFAIP6 | c.465C>T p.Y155= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs755909985, COSV54639916; called by muse, mutect2, varscan2
- TNXB | c.4434G>A p.A1478= (on ENST00000647633; = p.A1231= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs369459090; called by muse, mutect2, varscan2
- TPCN1 | c.1665C>T p.N555= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs538285886, COSV59237638; called by muse, mutect2, varscan2
- ZNF236 | c.4104G>A p.L1368= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99469447; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840271 C>T | 5'Flank (SNP) | VAF 38/66 reads (58%) | catalogued as COSV58345870; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827838 T>A | 3'Flank (SNP) | VAF 14/352 reads (4%) | catalogued as COSV59424310; called by muse, mutect2
